Somatic mutation profile of tumor specimen TARGET-40-PALHRL-01A (aliquot TARGET-40-PALHRL-01A-01D) from TARGET case TARGET-40-PALHRL, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.5 years (6,019 days).
Specimen TARGET-40-PALHRL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 737f251c-aee4-481a-8bd1-0e3976f39621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALHRL-10A (Blood Derived Normal), aliquot TARGET-40-PALHRL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67528542-aba4-4ac0-9c9e-a1dfabd82d48

The open-access MAF lists 54 somatic variants for this specimen: 25 protein-altering or splice-affecting, 13 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Intron 7, RNA 5, Nonsense Mutation 2, 5'UTR 1, 3'Flank 1, 3'UTR 1, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC242842.3 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 10/709 reads (1%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1185110962; called by muse, mutect2
- CCDC178 | c.2108G>T p.R703M (on ENST00000383096 / NM_001105528.3; = p.R665M on NM_198995.3) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100286036, COSV55759557; called by muse, mutect2
- DNAH2 | c.7864G>T p.V2622L | Missense Mutation (SNP) | VAF 291/2593 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV66722315, COSV66728476; called by muse, mutect2, varscan2
- DNAH9 | c.10729G>A p.V3577M | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771490376; called by muse, mutect2, varscan2
- EFR3A | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV99602702; called by muse, mutect2, varscan2
- ITIH1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs199510132; called by muse, varscan2
- RASSF9 | c.188C>G p.T63R | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.18); catalogued as COSV63433449; called by muse, mutect2, varscan2
- ANKRD18A | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- CFH | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- CYP11B1 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP24A1 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DCDC2 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 120/228 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EFR3A | c.1192A>G p.R398G | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- FLII | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 371/1762 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GLDC | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- GRIN1 | c.1833G>A p.W611* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- LRTM2 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MTMR7 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NCAN | c.1052T>A p.F351Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.19); called by muse, mutect2
- PCNX3 | c.2255A>T p.E752V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PRKACG | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PTEN | c.390_404delinsG p.T131Mfs*44 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by pindel, varscan2*
- SETD4 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TOP1 | c.897dup p.C300Mfs*2 | Frame Shift Ins (INS) | VAF 53/135 reads (39%) | called by mutect2, pindel, varscan2
- TRIM16L | c.138_144delinsAGAAAAA p.M46I | Missense Mutation (ONP) | VAF 43/138 reads (31%) | called by muse*, pindel
- ABCA8 | c.4476C>T p.I1492= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as COSV99286860; called by muse, mutect2, varscan2
- FAM47C | c.357G>A p.E119= | Silent (SNP) | VAF 133/159 reads (84%) | called by muse, mutect2, varscan2
- FUT11 | c.568C>T p.L190= | Silent (SNP) | VAF 28/50 reads (56%) | called by muse, varscan2
- INTS9 | c.1519C>T p.L507= | Silent (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- KIF22 | c.1593G>A p.V531= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, varscan2
- MTMR8 | c.1029C>T p.D343= | Silent (SNP) | VAF 21/25 reads (84%) | called by muse, mutect2, varscan2
- MYO15A | c.1303C>T p.L435= | Silent (SNP) | VAF 187/1066 reads (18%) | called by muse, varscan2
- MYO15A | c.1371C>T p.F457= | Silent (SNP) | VAF 68/624 reads (11%) | called by mutect2, varscan2
- NEUROD1 | c.141C>T p.N47= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs1046216784, COSV54549546; called by muse, mutect2, varscan2
- OR1G1 | c.234C>G p.V78= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV61029633; called by muse, mutect2, varscan2
- PIK3R5 | c.525C>T p.F175= | Silent (SNP) | VAF 72/461 reads (16%) | called by muse, mutect2, varscan2
- SEC24C | c.2229C>A p.V743= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- SEC24C | c.3018C>T p.F1006= | Silent (SNP) | VAF 106/492 reads (22%) | called by muse, varscan2
- AC098591.2 | n.1166G>T | RNA (SNP) | VAF 26/153 reads (17%) | catalogued as rs1158698732; called by muse, mutect2, varscan2
- ADGRE4P | n.165G>T | RNA (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- CCDC144B | n.1955G>A | RNA (SNP) | VAF 40/698 reads (6%) | called by muse, mutect2
- DNAH8 | c.10468-21C>T | Intron (SNP) | VAF 147/246 reads (60%) | called by muse, mutect2, varscan2
- DNAJC14 | chr12:55830818 C>T | 5'Flank (SNP) | VAF 9/23 reads (39%) | catalogued as rs867552378; called by muse, mutect2, varscan2
- EP400P1 | n.1234T>G | RNA (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- FUT11 | c.1334+23C>T | Intron (SNP) | VAF 86/151 reads (57%) | catalogued as rs764466612; called by muse, mutect2, varscan2
- FUT11 | c.*28C>T | 3'UTR (SNP) | VAF 76/157 reads (48%) | catalogued as rs780082918; called by muse, mutect2, varscan2
- GCOM2 | n.997G>C | RNA (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2397+22G>A | Intron (SNP) | VAF 15/103 reads (15%) | catalogued as rs1363952744; called by muse, mutect2, varscan2
- KCTD6 | c.-127C>T | 5'UTR (SNP) | VAF 8/24 reads (33%) | catalogued as rs550184361; called by muse, varscan2
- PCDHB6 | chr5:141157952 C>T | 3'Flank (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2
- PSG1 | c.1243+221A>C | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- SEC24C | c.2862+82C>G | Intron (SNP) | VAF 26/121 reads (21%) | called by muse, mutect2, varscan2
- ST7 | c.151+13623G>T | Intron (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- TBC1D26 | c.547-119C>G | Intron (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
